Somatic mutation profile of tumor specimen TARGET-10-PARIAD-03A (aliquot TARGET-10-PARIAD-03A-01D) from TARGET case TARGET-10-PARIAD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (596 days).
Specimen TARGET-10-PARIAD-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1b86272-17e3-4f6c-8a54-e5d0af0e7e5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARIAD-10A (Blood Derived Normal), aliquot TARGET-10-PARIAD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/017b9630-3fa4-48cf-92e2-273ffe28db8b

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNH6 | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs781598801, COSV59004879; called by muse, mutect2, varscan2
- KRT25 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 94/343 reads (27%) | catalogued as rs758921574, COSV56445775; called by muse, mutect2, varscan2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 18/160 reads (11%) | catalogued as rs750307488; called by mutect2, varscan2
- PCDHB7 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs574144062, COSV50772428; called by muse, mutect2
- SOAT2 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.341); catalogued as rs141175448; called by muse, mutect2, varscan2
- FCGBP | c.11014G>A p.D3672N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- TEX33 | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- DST | c.4297-1929G>A | Intron (SNP) | VAF 54/269 reads (20%) | catalogued as rs200347043, COSV55004610; called by muse, mutect2, varscan2
